Somatic mutation profile of tumor specimen TCGA-KO-8413-01A (aliquot TCGA-KO-8413-01A-11D-2310-10) from TCGA case TCGA-KO-8413, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 46.7 years (17,067 days).
Specimen TCGA-KO-8413-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05753b4f-546a-413b-91f2-f952af4e5d56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8413-11A (Solid Tissue Normal), aliquot TCGA-KO-8413-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f961a723-c347-47cc-b18d-827f378cb809

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAM160B1 | c.1798A>G p.R600G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.91); catalogued as rs1324636247, COSV100985289; called by muse, mutect2
- KALRN | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1215782059, COSV99562302; called by muse, mutect2
- MAP9 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100250747; called by muse, mutect2, varscan2
- MYO7A | c.6382A>T p.I2128F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100265054; called by muse, mutect2, varscan2
- SMG1 | c.7147C>A p.L2383M | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1279529744, COSV101245258; called by muse, mutect2, varscan2
- UBR5 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99639504; called by muse, mutect2
- ZNF521 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as rs766248011, COSV64125440; called by muse, mutect2, varscan2
- ZNF808 | c.1647G>T p.M549I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs753416971, COSV100707800; called by muse, mutect2, varscan2
- BRWD3 | c.4788A>G p.K1596= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100955672; called by muse, mutect2
- COL8A1 | c.2178G>A p.L726= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1427614943, COSV53735954; called by muse, mutect2, varscan2
- OR51T1 | c.636C>T p.D212= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as rs138268565; called by muse, mutect2, varscan2
- SERPINE1 | c.1116C>T p.P372= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as rs550385890; called by muse, mutect2, varscan2
